Somatic mutation profile of tumor specimen 0DCM1H from CCDI case PBBMKF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Spinal cord; Age at diagnosis: 14.1 years (5,148 days).
Specimen 0DCM1H: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 56f8478f-028b-4167-b1fc-7d79821c68f2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCM1B (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/630b526b-a09b-4ebe-9a40-12114772e71c

The open-access MAF lists 13 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Intron 1, Nonsense Mutation 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JPH4 | c.1730C>T p.S577L | Missense Mutation (SNP) | VAF 88/592 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs752956989, COSV100436519; called by muse, mutect2, varscan2
- SLCO1B1 | c.1985G>A p.G662E | Missense Mutation (SNP) | VAF 28/870 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV57009909; called by muse, mutect2
- ADAM29 | c.2276G>T p.S759I | Missense Mutation (SNP) | VAF 71/1663 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.164); called by muse, mutect2
- C17orf113 | c.1346G>A p.R449H | Missense Mutation (SNP) | VAF 257/835 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CNOT6L | c.1223G>A p.C408Y (on ENST00000504123 / NM_001286790.2; = p.C403Y on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 112/481 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MRPS30 | c.1231A>T p.K411* | Nonsense Mutation (SNP) | VAF 127/792 reads (16%) | called by muse, mutect2, varscan2
- NODAL | c.973T>G p.Y325D | Missense Mutation (SNP) | VAF 218/998 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- CDH26 | c.15C>T p.S5= | Silent (SNP) | VAF 136/503 reads (27%) | catalogued as rs764032810, COSV54844237; called by muse, mutect2, varscan2
- OR52E6 | c.900T>C p.I300= | Silent (SNP) | VAF 237/797 reads (30%) | catalogued as rs746512748; called by muse, mutect2, varscan2
- PIP5KL1 | c.870C>T p.H290= (on ENST00000388747 / NM_001135219.2; = p.H87= on NM_173492.1) | Silent (SNP) | VAF 265/1120 reads (24%) | catalogued as rs774976835, COSV55944165, COSV55944726; called by muse, mutect2, varscan2
- AC046195.1 | n.626T>C | RNA (SNP) | VAF 26/864 reads (3%) | called by muse, mutect2
- FKBP1A | c.-39C>T | 5'UTR (SNP) | VAF 50/504 reads (10%) | catalogued as rs767711358; called by muse, mutect2
- PLXND1 | c.3750+18C>T | Intron (SNP) | VAF 137/669 reads (20%) | catalogued as rs376690888; called by muse, mutect2, varscan2
